TCGA case TCGA-2G-AAII — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ce0e5768-fde9-49df-bb9f-7a386d17d730

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 37 years; Year of birth: 1966; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 37.7 years (13,761 days); Year of diagnosis: 2003; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IB; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,124 days (11.3 years); Ajcc serum tumor markers: S0.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 46 days; Treatment dose: 26 Gy; Treatment outcome: Complete Response; Number of fractions: 13; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,818 days (5.0 years); Disease response: Tumor Free.
- Days to follow up: 4,124 days (11.3 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -5: Lactate Dehydrogenase 321; Alpha Fetoprotein 7; Human Chorionic Gonadotropin 2.
- Day 28: Lactate Dehydrogenase 319; Alpha Fetoprotein 6; Human Chorionic Gonadotropin 2.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Risk factors: Undescended Testis; Undescended testis corrected: Yes; Undescended testis corrected age range: 2-11 months; Undescended testis corrected laterality: Bilateral; Undescended testis corrected method: Orchiopexy; Undescended testis history: Yes; Undescended testis history laterality: Bilateral.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAII-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 290 mg.
  Slide TCGA-2G-AAII-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAII-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAII-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
